Somatic mutation profile of tumor specimen TCGA-BR-A4IZ-01A (aliquot TCGA-BR-A4IZ-01A-32D-A25D-08) from TCGA case TCGA-BR-A4IZ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 45.7 years (16,695 days).
Specimen TCGA-BR-A4IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c096d62-fea6-438c-a01b-4c6587764975.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4IZ-10A (Blood Derived Normal), aliquot TCGA-BR-A4IZ-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c5c6e05-5238-4847-bfc0-7d0d0b82e226

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV59708544; called by muse, mutect2
- CTSF | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1222061377, COSV59750034; called by muse, mutect2
- DOCK2 | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177166833, COSV56944614; called by muse, mutect2
- PPP2R3A | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV53868475; called by muse, mutect2
- RFX1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs764655187, COSV54332355; called by muse, mutect2
- RXFP3 | c.59A>C p.K20T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV57507271; called by muse, mutect2
- SALL1 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.152); catalogued as rs1262719912, COSV99171461; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-205C>T | Intron (SNP) | VAF 17/194 reads (9%) | catalogued as rs146157959, COSV53575753; called by muse, mutect2
